Gene-level copy-number profile of tumor specimen ALCH-B36R-TTP1-A from ALCHEMIST case ALCH-B36R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 71.2 years (25,994 days).
Specimen ALCH-B36R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3acb062d-9b0e-4ce0-a7c6-3624457d254a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36R-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/f3238608-f199-4f9d-a4b3-78bc2b2cb3d3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 32; copy number 2: 263; copy number 3: 7,102; copy number 4: 37,228; copy number 5: 7,076; copy number 6: 3,610; copy number 7: 3,026; copy number 8: 41; copy number 10: 1; copy number 12: 1; copy number 14: 1; copy number 15: 2; copy number 27: 2; copy number 63: 6.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:25,172,635–25,178,819, 4 genes (within-gene range 0–4): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 12: AC113430.1.
- chr9:136,844,415–136,860,799, 3 genes, copy number 10–15 (within-gene range 5–15): AJM1, PHPT1, MAMDC4.
- chr9:136,969,243–136,971,990, 1 gene, copy number 14: LINC02692.
- chr13:113,208,193–113,453,524, 8 genes, copy number 27–63 (within-gene range 6–63): CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1.

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
